Somatic mutation profile of tumor specimen TCGA-92-8063-01G (aliquot TCGA-92-8063-01G-01D-A38P-08) from TCGA case TCGA-92-8063, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 52.5 years (19,193 days).
Specimen TCGA-92-8063-01G: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afd2a061-6dfb-43a2-adbe-9cc56306fc4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-92-8063-10A (Blood Derived Normal), aliquot TCGA-92-8063-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd4fa440-0abe-4524-8b3b-1618485ce3b6

The open-access MAF lists 348 somatic variants for this specimen: 282 protein-altering or splice-affecting, 60 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 244, Silent 60, Frame Shift Del 14, Nonsense Mutation 13, Splice Site 6, Intron 2, RNA 2, Splice Region 2, Frame Shift Ins 2, 5'Flank 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- SCN8A | c.2287A>G p.I763V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs794727128, COSV100633825; ClinVar: uncertain significance / not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 12/45 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, mutect2, varscan2
- ABCA4 | c.4895A>T p.N1632I | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100933125; called by muse, mutect2, varscan2
- ABCC8 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD131693, COSV100217267; called by muse, mutect2, varscan2
- ADAM29 | c.2225A>T p.Q742L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100822015; called by muse, mutect2, varscan2
- ADAMTS16 | c.2545C>G p.P849A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs752661811, COSV99941209; called by mutect2, varscan2
- ADARB2 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV101186901; called by muse, mutect2, varscan2
- AKAP6 | c.6641C>A p.S2214* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99800857; called by muse, mutect2, varscan2
- AKNA | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV56313738, COSV99800336; called by muse, mutect2, varscan2
- ANK2 | c.1594A>C p.T532P | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100001668; called by muse, mutect2, varscan2
- AQR | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); catalogued as COSV99333940; called by mutect2, varscan2
- ARFGEF3 | c.850A>T p.S284C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV99293500; called by muse, mutect2, varscan2
- ARHGAP11A | c.1026A>C p.K342N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100853247; called by muse, mutect2, varscan2
- ARHGAP32 | c.3064G>C p.V1022L (on ENST00000310343 / NM_001378025.1; = p.V673L on NM_014715.4) | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.07); catalogued as COSV100087881; called by muse, mutect2, varscan2
- ARID5B | c.796A>T p.S266C | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV99689678; called by muse, mutect2, varscan2
- ASAH2 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.562); catalogued as COSV100269941; called by muse, mutect2, varscan2
- ASTN2 | c.1787del p.P596Lfs*90 (on ENST00000313400 / NM_001365069.1; = p.P545Lfs*90 on NM_014010.5) | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as COSV57779456; called by mutect2, pindel, varscan2
- ATF2 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV99908702; called by mutect2, varscan2
- ATP6V1B1 | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs782185133, COSV99314113; called by muse, mutect2, varscan2
- BBS2 | c.1976A>C p.K659T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as COSV99802421; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2077A>G p.K693E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV100863758; called by muse, mutect2, varscan2
- BRCA1 | c.4396A>T p.S1466C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs1064794830, COSV100524169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD8 | c.3556G>T p.D1186Y | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99496836; called by muse, mutect2, varscan2
- BRINP1 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.948); catalogued as COSV56314480, COSV99775434; called by muse, mutect2, varscan2
- BTBD11 | c.2148A>G p.I716M (on ENST00000280758 / NM_001018072.2; = p.I253M on NM_001017523.2) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99775782; called by mutect2, varscan2
- BVES | c.336A>T p.L112F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV100114944; called by muse, mutect2
- C1orf159 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as COSV99618438; called by muse, varscan2
- CACNA1B | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99497485; called by muse, mutect2, varscan2
- CACNA1C | c.4784G>T p.R1595L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1313283709, COSV100214209; called by muse, mutect2, varscan2
- CACNA1E | c.2186T>C p.L729P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100702656; called by muse, mutect2, varscan2
- CALCRL | c.963A>T p.K321N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101130948; called by muse, mutect2, varscan2
- CAPN10 | c.930G>T p.R310S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.173); catalogued as COSV99550256; called by muse, mutect2, varscan2
- CAPN10 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs545243469, COSV99550259; called by muse, mutect2, varscan2
- CAPN6 | c.1471C>A p.P491T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV100136878; called by muse, mutect2
- CAPS2 | c.928T>C p.C310R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as COSV100157754; called by muse, mutect2, varscan2
- CCAR1 | c.2530G>T p.E844* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs1446238583; called by muse, mutect2
- CCDC91 | c.871T>A p.C291S | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.71); catalogued as COSV100081832; called by muse, mutect2, varscan2
- CDH4 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100848821; called by muse, mutect2, varscan2
- CDH4 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1423085482, COSV100848823; called by muse, mutect2
- CDH9 | c.2240C>A p.A747E | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427430666, COSV99144748; called by muse, mutect2, varscan2
- CDHR3 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as COSV100488362; called by muse, mutect2, varscan2
- CECR2 | c.4079G>A p.S1360N (on ENST00000342247 / NM_001290047.2; = p.S1176N on NM_001290046.1) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV99377963; called by muse, mutect2, varscan2
- CENPF | c.8693G>A p.R2898Q | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs774968388; called by muse, mutect2, varscan2
- CERCAM | c.489del p.L164Ffs*107 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | catalogued as rs1272182348, COSV65711673; called by mutect2, pindel, varscan2
- CFH | c.3691A>T p.R1231* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as rs1403643322, COSV100809573; called by muse, mutect2, varscan2
- CHAT | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100340157; called by muse, mutect2, varscan2
- CHIA | c.1126A>G p.K376E (on ENST00000343320; = p.K268E on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100588670; called by muse, mutect2, varscan2
- CHL1 | c.2457C>A p.D819E (on ENST00000397491 / NM_001253387.1; = p.D835E on NM_006614.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV56595802; called by muse, mutect2, varscan2
- CIB4 | c.515C>A p.P172Q | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99994835; called by muse, mutect2, varscan2
- CLCC1 | c.935T>A p.L312* (on ENST00000356970 / NM_001377464.1; = p.L262* on NM_015127.5) | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100206476; called by mutect2, varscan2
- CLEC12A | c.343A>T p.T115S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100429498; called by muse, mutect2, varscan2
- CLUH | c.3746G>T p.S1249I (on ENST00000435359; = p.S1288I on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1275045261, COSV101425743; called by muse, mutect2, varscan2
- CNDP1 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100722300; called by muse, mutect2, varscan2
- CNTLN | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as COSV99264115; called by muse, mutect2, varscan2
- CNTLN | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as rs1355066269, COSV99264116; called by muse, mutect2
- CNTN5 | c.1076T>A p.V359E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV54302168, COSV99676865; called by muse, mutect2
- CNTNAP2 | c.3845T>A p.L1282Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV100666612; called by muse, mutect2, varscan2
- CNTNAP4 | c.2243A>G p.N748S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1269323961, COSV100271452; called by muse, varscan2
- CNTROB | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV100972682; called by muse, mutect2, varscan2
- COL11A2 | c.3476G>A p.G1159D (on ENST00000341947 / NM_080680.3; = p.G1052D on NM_080679.2) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100554021; called by muse, mutect2, varscan2
- COL15A1 | c.1757C>A p.P586H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100897673; called by muse, mutect2, varscan2
- COL17A1 | c.3510G>C p.G1170= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100793170; called by muse, mutect2, varscan2
- COL19A1 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1304535162, COSV100506300; called by muse, mutect2, varscan2
- COL6A6 | c.2896T>C p.Y966H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.708); catalogued as COSV100650265; called by muse, mutect2, varscan2
- CPS1 | c.3205T>C p.Y1069H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768796044, COSV99243038; called by muse, mutect2, varscan2
- CRISP2 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs1260872846, COSV100189046; called by muse, mutect2, varscan2
- CRMP1 | c.146T>C p.L49S | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV100271850; called by muse, mutect2, varscan2
- CSMD2 | c.8216T>C p.V2739A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV99589954; called by muse, mutect2, varscan2
- CTNNA2 | c.870C>G p.D290E | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.123); catalogued as rs1428121684, COSV100784087, COSV99057505; called by muse, mutect2, varscan2
- CYSLTR1 | c.743C>A p.P248Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100964728; called by muse, mutect2, varscan2
- CYTIP | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV99938743; called by muse, mutect2, varscan2
- DEF8 | c.1001G>T p.C334F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV99240485; called by mutect2, varscan2
- DEPDC1B | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV99409610; called by muse, mutect2, varscan2
- DIP2C | c.2986-1G>T p.X996_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as rs1386286811, COSV99791695; called by muse, mutect2, varscan2
- DMD | c.5294C>G p.A1765G | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV100819721; called by muse, mutect2, varscan2
- DNAH10 | c.1456G>C p.E486Q (on ENST00000409039; = p.E425Q on NM_207437.3) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV101292256; called by muse, mutect2, varscan2
- DNAH7 | c.3298T>A p.F1100I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415222; called by muse, mutect2, varscan2
- DNAH7 | c.2131G>C p.D711H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100415224; called by muse, mutect2, varscan2
- DNAJC24 | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as COSV67917256; called by muse, mutect2, varscan2
- DPP10 | c.1390C>G p.Q464E | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs748703884, COSV100065208; called by muse, mutect2, varscan2
- DPP6 | c.1008C>A p.Y336* (on ENST00000377770 / NM_001364500.2; = p.Y274* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs1217879493, COSV100125590; called by muse, mutect2, varscan2
- DSCAM | c.1093A>T p.I365F | Missense Mutation (SNP) | VAF 61/352 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV101260157; called by muse, mutect2, varscan2
- DYTN | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV71752247, COSV71753007; called by muse, mutect2, varscan2
- E2F3 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100685996; called by muse, mutect2, varscan2
- ELMO2 | c.104A>T p.K35M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99281682; called by muse, mutect2, varscan2
- EP400 | c.5951G>T p.R1984M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1463144075, COSV100201237; called by mutect2, varscan2
- EPHA2 | c.2204A>G p.Y735C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626120; called by muse, mutect2, varscan2
- EPHA6 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101062713, COSV67559876; called by muse, mutect2, varscan2
- EPYC | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV99664658; called by muse, mutect2, varscan2
- ERBB4 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.06); catalogued as rs144842611, COSV61506927; called by muse, mutect2, varscan2
- ETNPPL | c.1147G>C p.A383P | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.418); catalogued as COSV99625248; called by muse, mutect2, varscan2
- EVX2 | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV100420671; called by muse, mutect2, varscan2
- EYS | c.1766+4T>G | Splice Region (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100676441; called by muse, mutect2, varscan2
- FAM199X | c.887G>C p.S296T | Missense Mutation (SNP) | VAF 110/152 reads (72%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100245546; called by muse, mutect2, varscan2
- FAT3 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99966204; called by muse, mutect2, varscan2
- FEZF2 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.238); catalogued as rs1215071273, COSV99334722; called by muse, mutect2, varscan2
- FGG | c.1105C>A p.H369N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.813); catalogued as COSV100271867; called by muse, mutect2, varscan2
- FRMD1 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV99349764; called by muse, mutect2, varscan2
- GABRG1 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99778048; called by muse, mutect2, varscan2
- GABRQ | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as COSV100941255, COSV100941282; called by muse, mutect2, varscan2
- GKN1 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV100933574, COSV65006917; called by mutect2, varscan2
- GLB1L2 | c.354-1G>T p.X118_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100335336; called by muse, mutect2, varscan2
- GPAA1 | c.761T>G p.L254R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100284059; called by muse, mutect2, varscan2
- GPD2 | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs1367064631, COSV100133249; called by muse, mutect2, varscan2
- GRIN3A | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62451769; called by muse, mutect2, varscan2
- GRM3 | c.1994G>T p.C665F | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV100862542; called by muse, mutect2, varscan2
- GSE1 | c.2407A>T p.T803S | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99496365, COSV99496554; called by muse, mutect2, varscan2
- GTF2B | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1320646621, COSV100980538; called by muse, mutect2, varscan2
- GUCA1C | c.177A>T p.Q59H | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV99226188; called by muse, mutect2, varscan2
- HCN1 | c.1655G>T p.S552I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100300258; called by muse, mutect2, varscan2
- HEPHL1 | c.2507C>A p.S836Y | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100243945; called by muse, mutect2, varscan2
- HIPK4 | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV52522258; called by muse, mutect2, varscan2
- HYOU1 | c.58G>C p.A20P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.152); catalogued as COSV101345606; called by muse, mutect2, varscan2
- IGSF11 | c.932T>C p.L311P (on ENST00000393775 / NM_001015887.3; = p.L310P on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100677316; called by muse, mutect2, varscan2
- IRS1 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100524513; called by muse, mutect2, varscan2
- IRS1 | c.1510C>G p.P504A | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100524516; called by muse, mutect2, varscan2
- ISL1 | c.122C>A p.A41E | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100045406; called by muse, mutect2, varscan2
- ITM2A | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100964456; called by muse, mutect2, varscan2
- KAT6B | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as rs752855653, COSV99768084; called by muse, mutect2, varscan2
- KCNB2 | c.1677C>A p.D559E | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.03); catalogued as COSV101578786; called by muse, mutect2, varscan2
- KCNMA1 | c.2936C>T p.P979L (on ENST00000286628 / NM_001161352.2; = p.P921L on NM_002247.4) | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV99697367; called by muse, mutect2, varscan2
- KIAA1549L | c.3489C>A p.H1163Q (on ENST00000321505; = p.H1460Q on NM_012194.3) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs374432618, COSV99683501; called by muse, mutect2, varscan2
- KIF20B | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV53315916, COSV99590031; called by muse, mutect2, varscan2
- KIF26B | c.5837G>A p.R1946Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs374777159, COSV63645163; called by muse, mutect2, varscan2
- KLHL4 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); catalogued as COSV100909569; called by muse, mutect2, varscan2
- KLK5 | c.28T>A p.W10R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1379124586, COSV100307042; called by muse, mutect2, varscan2
- LAMA1 | c.2947T>A p.C983S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101056400; called by muse, mutect2, varscan2
- LAMA2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs149654569; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LILRB5 | c.1654G>T p.D552Y (on ENST00000449561 / NM_001081442.3; = p.D551Y on NM_006840.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV100300411; called by muse, varscan2
- LNX2 | c.1661A>T p.E554V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as COSV100310710; called by muse, mutect2, varscan2
- LRIT2 | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100258875; called by muse, mutect2, varscan2
- LYZL4 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99821226; called by muse, mutect2, varscan2
- LZTS2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs1340450392, COSV100932177; called by muse, mutect2, varscan2
- MAD2L1BP | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as rs540166614, COSV100937827; called by mutect2, varscan2
- MAGEL2 | c.3128G>T p.R1043L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV58569384; called by mutect2, varscan2
- MARK4 | c.842C>G p.T281R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99488297; called by muse, mutect2, varscan2
- MCM4 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50631952; called by muse, mutect2
- MCM5 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs771693792, COSV99331693; called by muse, varscan2
- MED17 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52602774; called by muse, mutect2, varscan2
- MED23 | c.2151G>T p.Q717H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.709); catalogued as COSV100645009; called by muse, mutect2, varscan2
- MEIS2 | c.796G>T p.D266Y (on ENST00000561208 / NM_170675.5; = p.D253Y on NM_002399.3) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99576469; called by muse, mutect2, varscan2
- MMP16 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99688250; called by muse, varscan2
- MOGAT2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV52219765, COSV99549550; called by muse, mutect2, varscan2
- MRPL3 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.319); catalogued as rs1175826475, COSV99394792; called by muse, mutect2, varscan2
- MS4A12 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs781773125, COSV50015208, COSV99188921; called by muse, mutect2, varscan2
- MUC17 | c.3760G>T p.A1254S | Missense Mutation (SNP) | VAF 149/580 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100073259; called by muse, mutect2, varscan2
- MUC3A | c.7985del p.S2662Ffs*13 | Frame Shift Del (DEL) | VAF 84/531 reads (16%) | catalogued as COSV100113839, COSV60221189; called by mutect2, pindel, varscan2
- MYH7 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62519770; called by muse, mutect2, varscan2
- MYH8 | c.1735C>A p.H579N | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101238406; called by muse, mutect2
- MYH8 | c.1733C>A p.A578D | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV101238407; called by muse, mutect2
- MYO16 | c.2647T>C p.Y883H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99193905; called by muse, mutect2, varscan2
- MYO5B | c.4099G>A p.A1367T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53211753; called by muse, mutect2, varscan2
- MYOM2 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1201319689, COSV100037488; called by muse, mutect2, varscan2
- NAALAD2 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100428445, COSV58967507; called by muse, mutect2, varscan2
- NAV3 | c.5515C>T p.Q1839* (on ENST00000397909 / NM_001024383.2; = p.Q1817* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99891002; called by muse, mutect2, varscan2
- NCAM2 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as COSV99523029; called by muse, mutect2, varscan2
- NEB | c.10123G>C p.A3375P | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99423015; called by muse, mutect2, varscan2
- NIBAN2 | c.1543-2A>G p.X515_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100031499; called by muse, mutect2, varscan2
- NLGN1 | c.1253T>C p.F418S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100849376, COSV64323677; called by muse, mutect2, varscan2
- NLGN4X | c.1783C>A p.P595T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52024681, COSV99321784; called by muse, mutect2, varscan2
- NLRP4 | c.306C>A p.H102Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100016321, COSV56723746; called by mutect2, varscan2
- NRXN1 | c.3553G>C p.G1185R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100640268; called by muse, mutect2, varscan2
- NXF3 | c.373A>T p.N125Y | Missense Mutation (SNP) | VAF 94/121 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV101221955; called by muse, mutect2, varscan2
- OBSCN | c.6643G>T p.A2215S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.291); catalogued as rs1300804616; called by muse, mutect2, varscan2
- OGDHL | c.2551C>T p.H851Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV100934322; called by muse, mutect2, varscan2
- OR10G4 | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV100304832; called by muse, mutect2, varscan2
- OR1A2 | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101126361; called by muse, mutect2, varscan2
- OR2AG2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV58456147; called by muse, mutect2, varscan2
- OR2J2 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV101013366; called by muse, mutect2, varscan2
- OR4C15 | c.583G>A p.G195S (on ENST00000314644; = p.G141S on NM_001001920.2) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.098); catalogued as rs201504039, COSV100115556, COSV100115675; called by mutect2, varscan2
- OR4X1 | c.678C>G p.H226Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100186685, COSV60724014; called by muse, mutect2, varscan2
- OR5D13 | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100686871, COSV100686945, COSV62333789; called by muse, mutect2, varscan2
- OR6K3 | c.572A>G p.H191R (on ENST00000368146; = p.H175R on NM_001005327.2) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV100933855; called by muse, mutect2, varscan2
- OR6K6 | c.439G>T p.A147S (on ENST00000368144; = p.A123S on NM_001005184.1) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV100933771; called by muse, mutect2, varscan2
- OR6K6 | c.746T>C p.I249T (on ENST00000368144; = p.I225T on NM_001005184.1) | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs900404971, COSV100933743; called by muse, mutect2, varscan2
- OR6M1 | c.304T>A p.Y102N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100484076; called by muse, mutect2, varscan2
- P4HA2 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772697844, COSV99387026; called by muse, mutect2, varscan2
- PAAF1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100142479; called by muse, mutect2, varscan2
- PCDH1 | c.3266A>G p.Y1089C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415892100, COSV99746204; called by muse, mutect2, varscan2
- PCDH15 | c.4816G>C p.E1606Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.04); catalogued as COSV100904366, COSV64727525; called by muse, varscan2
- PCDH18 | c.491C>A p.P164Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100787312; called by muse, mutect2, varscan2
- PCDHB6 | c.1152G>C p.E384D | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV99170131; called by muse, mutect2, varscan2
- PCDHB7 | c.1711C>A p.P571T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.645); catalogued as rs1195859347, COSV99176949; called by muse, mutect2, varscan2
- PCDHGA6 | c.1338del p.N446Kfs*29 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | catalogued as COSV53950867; called by mutect2, pindel, varscan2
- PCDHGA9 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV99538397; called by muse, mutect2, varscan2
- PCK2 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99394389; called by muse, mutect2, varscan2
- PCLO | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.022); catalogued as COSV100432699, COSV61657319; called by muse, mutect2, varscan2
- PCOLCE2 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as COSV99930646; called by muse, mutect2, varscan2
- PGK2 | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505500; called by muse, mutect2, varscan2
- PHIP | c.977G>C p.C326S | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99244109; called by muse, mutect2, varscan2
- PIK3C2A | c.2851G>T p.A951S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV99790738; called by muse, mutect2, varscan2
- PLCB4 | c.3057G>T p.Q1019H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV99595486; called by muse, mutect2, varscan2
- PLEK | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99310962; called by muse, mutect2, varscan2
- PLPPR1 | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100883285; called by muse, mutect2
- PNPLA8 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs750960133, COSV57554940; called by muse, mutect2, varscan2
- POSTN | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756971818, COSV101123330; called by muse, varscan2
- POTEF | c.2807T>C p.L936P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV100664933, COSV100664978; called by muse, mutect2, varscan2
- PPM1H | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs756011853, COSV99955848; called by mutect2, varscan2
- PROX2 | c.1598A>G p.N533S (on ENST00000556489 / NM_001243007.1; = p.N306S on NM_001080408.2) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV101507808; called by muse, mutect2
- PSMA4 | c.477G>T p.W159C | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99245531; called by muse, mutect2, varscan2
- PTPN3 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1378349248, COSV99355732; called by muse, mutect2, varscan2
- PTPRD | c.2563G>T p.G855C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100644805; called by muse, mutect2, varscan2
- PTPRE | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs145040171; called by muse, mutect2, varscan2
- RASA1 | c.2344G>T p.D782Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99169826; called by muse, mutect2, varscan2
- REG1A | c.321+1del | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | catalogued as COSV52071180, COSV99286689; called by mutect2, pindel, varscan2
- RELN | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV100633755, COSV100634990; called by muse, mutect2, varscan2
- RET | c.340C>A p.R114S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs747483905, CM1110128, COSV100393626, COSV60686075; called by mutect2, varscan2
- RFX2 | c.1752G>A p.W584* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100353800; called by muse, mutect2, varscan2
- RFX5 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100923878; called by muse, mutect2, varscan2
- RGS22 | c.3780C>A p.H1260Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.118); catalogued as rs1178479538, COSV100693265; called by muse, mutect2, varscan2
- RIMS4 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1298980566, COSV65719583; called by muse, mutect2, varscan2
- RNF214 | c.914A>T p.Q305L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100326688; called by muse, mutect2, varscan2
- RP1L1 | c.1224G>T p.W408C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770516421, COSV101223255, COSV66760700; called by muse, mutect2, varscan2
- RYR3 | c.8066A>T p.K2689I (on ENST00000389232; = p.K2690I on NM_001036.6) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as COSV101212773; called by muse, mutect2, varscan2
- RYR3 | c.11190C>A p.F3730L (on ENST00000389232; = p.F3731L on NM_001036.6) | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as rs1243162995, COSV101212775; called by muse, mutect2, varscan2
- SAMD4A | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV99200676; called by muse, mutect2, varscan2
- SATB1 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100113182; called by muse, mutect2, varscan2
- SATB2 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs1559175031, COSV99611309; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN2A | c.4843A>G p.I1615V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1177670695, COSV99331687; called by muse, mutect2, varscan2
- SCN3A | c.4256G>T p.W1419L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99325390, COSV99327020; called by muse, mutect2, varscan2
- SEC24A | c.2231G>T p.G744V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59746400; called by muse, mutect2, varscan2
- SEMA4F | c.556del p.X186_splice | Splice Site (DEL) | VAF 19/68 reads (28%) | catalogued as rs749720924, COSV60283870; called by mutect2, pindel, varscan2
- SHPRH | c.408G>T p.R136S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as COSV99262071; called by muse, mutect2, varscan2
- SLC12A5 | c.2612A>G p.H871R (on ENST00000454036 / NM_001134771.2; = p.H848R on NM_020708.5) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV99716052; called by muse, mutect2, varscan2
- SMARCA4 | c.2534del p.V845Afs*13 | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | catalogued as rs1285069421; called by mutect2, pindel, varscan2
- SMIM19 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV101330339; called by muse, mutect2, varscan2
- SORCS3 | c.1827C>A p.Y609* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100865110; called by muse, mutect2, varscan2
- SPRY4 | c.862G>T p.G288W (on ENST00000434127 / NM_001127496.3; = p.G311W on NM_030964.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.186); catalogued as rs148661341, COSV100702180; called by muse, mutect2, varscan2
- SULF2 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100737201; called by muse, mutect2, varscan2
- SV2C | c.989G>T p.C330F | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100456165; called by muse, mutect2, varscan2
- SYCP2 | c.1821T>A p.C607* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV100698256; called by muse, mutect2, varscan2
- TAC1 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100071126; called by muse, mutect2, varscan2
- TAS2R41 | c.785A>C p.N262T | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV101281476, COSV101281489; called by muse, mutect2, varscan2
- TBX18 | c.792C>A p.H264Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100858512; called by muse, mutect2, varscan2
- TMEM108 | c.726G>T p.W242C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.415); catalogued as rs1483358420, COSV100418837; called by muse, mutect2, varscan2
- TMEM252 | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101051117; called by muse, mutect2, varscan2
- TNIP3 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs370464126, COSV99284489; called by muse, mutect2, varscan2
- TP53TG5 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767966819, COSV101022343; called by mutect2, varscan2
- TPH2 | c.810G>C p.R270S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.205); catalogued as COSV100422084; called by muse, mutect2, varscan2
- TRPC1 | c.2097T>G p.S699R (on ENST00000476941 / NM_001251845.2; = p.S665R on NM_003304.4) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99858786; called by muse, mutect2, varscan2
- TRPC4 | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV100156847; called by muse, mutect2, varscan2
- TTC12 | c.795del p.I266Lfs*4 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs1555145313; called by mutect2, pindel, varscan2
- TTC14 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99932053; called by muse, mutect2, varscan2
- TTC23 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100018748; called by muse, mutect2, varscan2
- TTLL7 | c.1277G>C p.R426P | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99552402; called by mutect2, varscan2
- TTN | c.95915T>C p.V31972A (on ENST00000591111; = p.V24548A on NM_003319.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | PolyPhen benign (0.15); catalogued as COSV100612821; called by muse, mutect2, varscan2
- UBR4 | c.13161G>C p.K4387N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100920805, COSV64383086; called by muse, mutect2, varscan2
- UNC13A | c.2863T>A p.F955I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV99408357; called by muse, mutect2, varscan2
- USP37 | c.861C>A p.D287E | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV99294430; called by muse, mutect2, varscan2
- VKORC1 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.389); catalogued as COSV99762316; called by mutect2, varscan2
- VN1R2 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs267605652, COSV100447935; called by muse, mutect2, varscan2
- VPS13A | c.5274G>A p.W1758* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100652790; called by muse, mutect2, varscan2
- WASHC2A | c.3531G>T p.E1177D | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.05); catalogued as COSV99254651; called by muse, mutect2, varscan2
- WDR20 | c.918G>C p.W306C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085092, COSV54475297; called by muse, mutect2, varscan2
- WDR91 | c.1554C>A p.S518R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV100615695; called by muse, mutect2, varscan2
- WNT9A | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs773109746, COSV99688221; called by muse, mutect2, varscan2
- WRN | c.2089-2A>T p.X697_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99989048; called by muse, mutect2, varscan2
- XIRP2 | c.6569C>T p.P2190L (on ENST00000628543; = p.P2365L on NM_152381.6) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.093); catalogued as rs752276378, COSV99742939; called by muse, mutect2, varscan2
- YARS2 | c.937T>G p.S313A | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100256405; called by muse, mutect2, varscan2
- ZBTB49 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100552466; called by muse, mutect2, varscan2
- ZC3H12C | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.787); catalogued as COSV99584976; called by muse, mutect2, varscan2
- ZFHX3 | c.7228A>G p.T2410A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51710767, COSV51720737; called by muse, mutect2, varscan2
- ZFYVE9 | c.818A>G p.Q273R | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs773075420, COSV99820028; called by muse, mutect2, varscan2
- ZNF585B | c.2309G>T p.*770Lext*30 | Nonstop Mutation (SNP) | VAF 48/114 reads (42%) | catalogued as rs1453038873, COSV100459451; called by muse, mutect2, varscan2
- ZWINT | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV100571513; called by muse, mutect2
- ATP10B | c.1542del p.I515Sfs*26 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, varscan2
- C10orf82 | c.265del p.L89* | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.1259del p.G420Efs*39 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- DDI1 | c.69del p.D24Tfs*71 | Frame Shift Del (DEL) | VAF 18/114 reads (16%) | called by mutect2, pindel, varscan2
- DYSF | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2
- FAM214B | c.1394dup p.L465Ffs*6 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- KCNT2 | c.2596-1G>T p.X866_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- MRC1 | c.2360C>A p.P787H | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NLRP8 | c.1252_1253del p.Q418Vfs*15 | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | called by pindel, varscan2
- PCLO | c.8126A>G p.H2709R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- PCNX1 | c.6278_6279insG p.T2094Hfs*10 | Frame Shift Ins (INS) | VAF 10/37 reads (27%) | called by mutect2, pindel*, varscan2
- PKHD1 | c.6257del p.G2086Vfs*25 | Frame Shift Del (DEL) | VAF 27/110 reads (25%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.2158A>T p.S720C | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYT9 | c.175del p.V59Sfs*58 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- TRPV4 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.5873C>T p.P1958L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARL4A | c.543A>G p.K181= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs1172200396, COSV63319581; called by muse, mutect2, varscan2
- ATXN7 | c.1452T>C p.T484= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99894448; called by mutect2, varscan2
- CATSPER1 | c.2214C>G p.L738= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100375951, COSV56410326; called by muse, mutect2, varscan2
- CDADC1 | c.852C>A p.A284= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV51910443, COSV99212562; called by mutect2, varscan2
- CEP83 | c.1239G>A p.V413= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as COSV100352849; called by muse, mutect2, varscan2
- CLVS1 | c.186C>G p.T62= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV57973048; called by muse, mutect2, varscan2
- COL15A1 | c.1758C>T p.P586= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100897674; called by muse, mutect2, varscan2
- CRACR2A | c.147A>G p.L49= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99364995, COSV99365421; called by muse, mutect2, varscan2
- CSMD1 | c.10158G>C p.V3386= (on ENST00000520002; = p.V3385= on NM_033225.6) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100147907; called by muse, mutect2, varscan2
- CSMD2 | c.4632T>A p.A1544= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV99589957; called by muse, mutect2, varscan2
- CSMD2 | c.3678A>G p.E1226= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99589959; called by muse, mutect2, varscan2
- CSMD3 | c.3141C>G p.P1047= (on ENST00000297405 / NM_001363185.1; = p.P943= on NM_052900.3) | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV52181248, COSV99834436; called by muse, mutect2, varscan2
- CUBN | c.3306T>C p.Y1102= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100912680; called by muse, mutect2, varscan2
- CYP4F2 | c.720C>A p.L240= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99171083; called by muse, mutect2, varscan2
- DCHS1 | c.5055T>C p.T1685= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100202049; called by muse, varscan2
- DPP10 | c.1389C>A p.R463= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as COSV100065201, COSV100070480; called by muse, mutect2, varscan2
- FAM81B | c.579A>T p.T193= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV99352534, COSV99352840; called by muse, mutect2, varscan2
- FNDC7 | c.1143G>T p.V381= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as rs1408416449, COSV99601242; called by muse, mutect2, varscan2
- GGA3 | c.930C>G p.T310= (on ENST00000537686 / NM_138619.4; = p.T277= on NM_014001.5) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99822083; called by muse, mutect2, varscan2
- GLP2R | c.540G>T p.L180= | Silent (SNP) | VAF 53/220 reads (24%) | catalogued as COSV99302008, COSV99302538; called by muse, mutect2, varscan2
- GPN2 | c.546C>T p.L182= | Silent (SNP) | VAF 32/255 reads (13%) | catalogued as COSV100658795; called by muse, mutect2, varscan2
- GRID2 | c.2169G>C p.L723= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99940899; called by muse, mutect2, varscan2
- ITPKC | c.1443C>T p.S481= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs770108570, COSV99648744; called by muse, mutect2, varscan2
- KCNT1 | c.2592G>A p.V864= (on ENST00000488444; = p.V883= on NM_020822.3) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs766768602, COSV99705754; called by mutect2, varscan2
- KIAA1958 | c.624C>T p.P208= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs781436748, COSV100516064; called by muse, mutect2, varscan2
- LCP2 | c.429G>T p.A143= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs199666234, COSV50454211; called by mutect2, varscan2
- LRRC30 | c.121C>A p.R41= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV101274369, COSV101274411; called by muse, mutect2, varscan2
- MMRN1 | c.3336T>A p.T1112= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV99307118; called by muse, mutect2, varscan2
- MSTN | c.903T>A p.P301= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99640693; called by muse, mutect2, varscan2
- NPY1R | c.402T>C p.I134= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99648762; called by muse, mutect2, varscan2
- NSMCE2 | c.189G>A p.K63= | Silent (SNP) | VAF 44/308 reads (14%) | catalogued as COSV99786816; called by muse, mutect2, varscan2
- NUP107 | c.2682G>A p.K894= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV57499434; called by muse, mutect2, varscan2
- OR10Z1 | c.24C>T p.S8= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV63525653; called by muse, mutect2, varscan2
- OR11H1 | c.66T>C p.S22= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as rs1222438405, COSV99421811; called by mutect2, varscan2
- OR14I1 | c.594G>T p.L198= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100700482; called by muse, mutect2, varscan2
- OR5H6 | c.480A>G p.L160= (on ENST00000642105; = p.L144= on NM_001005479.2) | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as COSV101051774; called by muse, mutect2, varscan2
- PAPPA2 | c.4062T>C p.A1354= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4980G>T p.L1660= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100868139, COSV62790332; called by muse, mutect2, varscan2
- PATL1 | c.1611G>A p.E537= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1186055382; called by muse, mutect2, varscan2
- PCDHB6 | c.1677G>A p.V559= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99170134; called by muse, mutect2, varscan2
- PCDHGA4 | c.2400C>T p.I800= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV99538395; called by muse, mutect2, varscan2
- PLXNA4 | c.2331G>C p.L777= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100324326; called by muse, mutect2, varscan2
- PPP1R15A | c.1563C>T p.P521= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs762302741, COSV99566049; called by mutect2, varscan2
- PROS1 | c.1653G>T p.L551= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1283277633, COSV101260486; called by muse, mutect2, varscan2
- RGS18 | c.510C>A p.L170= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100817775; called by muse, mutect2, varscan2
- RHCE | c.18G>A p.P6= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1440527105, COSV99604038; called by muse, mutect2, varscan2
- SEMG2 | c.1437C>T p.N479= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV101034078; called by muse, mutect2, varscan2
- SLC22A18 | c.723G>T p.P241= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100388806; called by muse, varscan2
- SLC39A8 | c.963G>T p.A321= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100765736; called by muse, mutect2
- STON1-GTF2A1L | c.3177A>T p.T1059= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV100561864; called by muse, mutect2, varscan2
- STXBP5L | c.2505A>G p.L835= | Silent (SNP) | VAF 62/190 reads (33%) | catalogued as rs1241012078, COSV99874150; called by muse, mutect2, varscan2
- SYNE1 | c.13272G>A p.Q4424= (on ENST00000367255 / NM_182961.4; = p.Q4353= on NM_033071.3) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99564368; called by muse, mutect2, varscan2
- TAS2R30 | c.405G>C p.G135= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV101114828; called by muse, mutect2, varscan2
- TENM1 | c.417G>T p.R139= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV100950045; called by muse, mutect2, varscan2
- TMEM14C | c.60G>T p.L20= | Silent (SNP) | VAF 67/262 reads (26%) | catalogued as COSV99994498; called by muse, mutect2, varscan2
- UTP20 | c.7284A>G p.E2428= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99881641; called by muse, mutect2
- VSIG4 | c.186A>G p.S62= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV101038159; called by muse, mutect2, varscan2
- ZIK1 | c.750C>A p.G250= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100277486; called by muse, mutect2, varscan2
- ZNF365 | c.162A>G p.E54= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1190307347, COSV101237960; called by muse, mutect2, varscan2
- ZNF536 | c.1992G>C p.L664= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs933375578, COSV100835239, COSV100835248; called by muse, mutect2
- AL353804.4 | chrX:73826091 del C | 5'Flank (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- DCHS2 | n.3827C>A | RNA (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100601776; called by muse, mutect2, varscan2
- LPAL2 | n.102G>A | RNA (SNP) | VAF 44/267 reads (16%) | catalogued as rs1288111311; called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039552 A>C | 5'Flank (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44072G>A | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as rs1158039321, COSV101043850; called by muse, mutect2, varscan2
- TTN | c.10360+4425A>C | Intron (SNP) | VAF 14/95 reads (15%) | catalogued as COSV100612823; called by muse, mutect2, varscan2
